Somatic mutation profile of tumor specimen TCGA-A2-A0D3-01A (aliquot TCGA-A2-A0D3-01A-11D-A10Y-09) from TCGA case TCGA-A2-A0D3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 42.5 years (15,524 days).
Specimen TCGA-A2-A0D3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b961834-58d4-4062-8951-b4737b578beb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0D3-10A (Blood Derived Normal), aliquot TCGA-A2-A0D3-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c147e69-ae6c-44f9-bef5-9a64a2e0a952

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 55/119 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.3622C>T p.R1208* | Nonsense Mutation (SNP) | VAF 44/108 reads (41%) | catalogued as COSV53239154, COSV99486817; called by muse, mutect2, varscan2
- CD19 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs374321123; called by muse, mutect2
- CEP350 | c.5794G>T p.V1932L | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV62600206; called by muse, mutect2, varscan2
- CXCR1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.258); catalogued as rs56030518; called by muse, mutect2, varscan2
- IL17B | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs777464695, COSV55783132; called by muse, mutect2, varscan2
- MAGEC3 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.414); catalogued as COSV53575710, COSV53577836; called by muse, mutect2, varscan2
- MROH9 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 68/390 reads (17%) | catalogued as COSV63010549, COSV63011949; called by muse, mutect2, varscan2
- MYH14 | c.5599C>T p.R1867W | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1272434745, COSV51813320; called by muse, mutect2, varscan2
- NLRP3 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 78/503 reads (16%) | catalogued as rs1191108022, COSV60221776, COSV60222875; called by muse, mutect2, varscan2
- PKNOX2 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as rs762099105, COSV53543136; called by muse, mutect2, varscan2
- PLEKHA5 | c.1251G>A p.W417* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100164133; called by muse, mutect2
- POLI | c.2140T>G p.Y714D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV54188338; called by muse, mutect2, varscan2
- PTPRU | c.4162G>A p.G1388S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159108440, COSV60524296; called by muse, mutect2, varscan2
- SLC13A1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52009520; called by muse, mutect2, varscan2
- SLC18A1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52347354; called by muse, mutect2, varscan2
- SYBU | c.1075T>G p.F359V (on ENST00000276646 / NM_001099754.2; = p.F358V on NM_017786.6) | Missense Mutation (SNP) | VAF 63/106 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52615659; called by muse, mutect2, varscan2
- TFIP11 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV53225853; called by muse, mutect2, varscan2
- DNAJC2 | c.1196_1197del p.L399Hfs*21 | Frame Shift Del (DEL) | VAF 72/229 reads (31%) | called by mutect2, pindel, varscan2
- GATA3 | c.1030dup p.Y344Lfs*8 | Frame Shift Ins (INS) | VAF 30/127 reads (24%) | called by mutect2, pindel, varscan2
- KMT2C | c.432del p.L145* | Frame Shift Del (DEL) | VAF 75/280 reads (27%) | called by mutect2, pindel, varscan2
- C11orf45 | c.393C>A p.G131= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV57964152, COSV57964432; called by muse, mutect2, varscan2
- CPT1C | c.664C>A p.R222= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1477576811, COSV54920207, COSV99773483; called by muse, mutect2
- EVI5 | c.822T>C p.Y274= | Silent (SNP) | VAF 61/179 reads (34%) | catalogued as rs770323517, COSV63278618; called by muse, mutect2, varscan2
- GPHA2 | c.117A>T p.T39= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV51209893; called by muse, mutect2, varscan2
- GRIA2 | c.1920C>T p.N640= | Silent (SNP) | VAF 86/234 reads (37%) | catalogued as COSV52386115; called by muse, mutect2, varscan2
- LTA4H | c.990C>T p.C330= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as rs369690251; called by muse, mutect2, varscan2
- NOTCH2 | c.7143C>T p.G2381= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as COSV56686674; called by muse, mutect2, varscan2
